Somatic mutation profile of tumor specimen TCGA-76-6193-01A (aliquot TCGA-76-6193-01A-11D-1696-08) from TCGA case TCGA-76-6193, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.7 years (28,742 days).
Specimen TCGA-76-6193-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0b87a33-e1ae-417b-bc3e-e682ac8af9f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-6193-10A (Blood Derived Normal), aliquot TCGA-76-6193-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17a8ed39-c0a6-4d80-a860-e129421a0f07

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 13, Nonsense Mutation 4, Frame Shift Del 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs786202752, CM942117, HM090066, COSV52692291, COSV52711720, COSV52741190, COSV52782333; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ACTG2 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs749903398, COSV61827683; called by muse, mutect2, varscan2
- APOBEC3F | c.745C>A p.H249N | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57910847, COSV57911871; called by muse, mutect2, varscan2
- ATG12 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 19/124 reads (15%) | catalogued as rs769843692, COSV57243153; called by muse, mutect2, varscan2
- CATSPERD | c.475G>C p.V159L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as COSV67537229; called by muse, mutect2, varscan2
- CDCP1 | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 14/329 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.189); catalogued as COSV56107955; called by muse, mutect2
- DCAF12L1 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64421605; called by muse, mutect2, varscan2
- DLGAP2 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs747744035, COSV70103813; called by muse, mutect2
- IGSF9 | c.3461G>A p.R1154H (on ENST00000368094 / NM_001135050.2; = p.R1138H on NM_020789.4) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs143248267; called by muse, mutect2, varscan2
- ILDR1 | c.1451A>C p.D484A (on ENST00000344209 / NM_001199799.2; = p.D440A on NM_175924.4) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV56553778; called by muse, mutect2, varscan2
- ITLN2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770677250, COSV63537643; called by muse, mutect2, varscan2
- LAMA2 | c.2075T>C p.F692S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as COSV70354854; called by muse, mutect2, varscan2
- LAMA5 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.828); catalogued as rs1178002208, COSV53372012; called by muse, mutect2, varscan2
- LAMC2 | c.2863C>T p.L955F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51459642; called by muse, mutect2, varscan2
- MAPK3 | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs777053157, COSV53774389; called by muse, mutect2, varscan2
- MPDZ | c.3255A>G p.K1085= | Splice Region (SNP) | VAF 16/54 reads (30%) | catalogued as COSV59924365; called by muse, mutect2, varscan2
- MPL | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs137952228; called by muse, mutect2, varscan2
- N4BP2 | c.4424C>T p.S1475F | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV54706782; called by muse, varscan2
- NAA11 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as rs957566798, COSV54513781; called by muse, mutect2, varscan2
- NOS1 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1195781821, COSV57608819; called by muse, mutect2, varscan2
- OR5D16 | c.366T>A p.Y122* | Nonsense Mutation (SNP) | VAF 23/125 reads (18%) | catalogued as COSV65722929; called by muse, mutect2, varscan2
- PDYN | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs766877230, COSV54101975; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCE1 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs752185437, COSV53371526; called by muse, mutect2, varscan2
- POC1B | c.662T>G p.L221R | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100544416; called by muse, mutect2, varscan2
- RALGAPA2 | c.4364C>G p.S1455C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs759968933, COSV52510664; called by muse, mutect2, varscan2
- SHTN1 | c.867A>T p.E289D | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs145640256; called by muse, mutect2, varscan2
- SLC12A3 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs139743444; called by muse, mutect2, varscan2
- SLC15A2 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1286522851, COSV55200884; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.750A>T p.K250N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | PolyPhen possibly damaging (0.628); catalogued as COSV60349222; called by muse, mutect2, varscan2
- TP53 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs563378859, CD156964, COSV52711846, COSV52730924, COSV53119766; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- VAMP7 | c.576C>G p.I192M | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.772); catalogued as COSV52902002, COSV52902802; called by muse, mutect2, varscan2
- VIL1 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs1344522901, COSV50288101; called by muse, mutect2, varscan2
- VSIG8 | c.321C>G p.Y107* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as COSV63653558; called by muse, mutect2, varscan2
- ZUP1 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV63944817; called by muse, mutect2, varscan2
- OR1N1 | c.576del p.N193Tfs*3 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- PYGO1 | c.554_557del p.S185Kfs*31 | Frame Shift Del (DEL) | VAF 23/109 reads (21%) | called by mutect2, pindel, varscan2
- ALOX15B | c.6C>T p.A2= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV66480173; called by muse, mutect2, varscan2
- ANKRD50 | c.2598T>C p.L866= | Silent (SNP) | VAF 29/163 reads (18%) | catalogued as COSV72386293; called by muse, mutect2, varscan2
- BORA | c.1659A>G p.S553= (on ENST00000613797; = p.S478= on NM_024808.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/233 reads (30%) | catalogued as COSV64695866; called by muse, mutect2, varscan2
- BPTF | c.6315A>G p.Q2105= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs1255447151, COSV58846451; called by muse, mutect2, varscan2
- CD1B | c.78C>T p.T26= | Silent (SNP) | VAF 69/292 reads (24%) | catalogued as COSV63805178; called by muse, mutect2, varscan2
- GPR45 | c.498G>A p.S166= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99306702; called by muse, mutect2
- HCN3 | c.969C>G p.P323= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100855702, COSV64235188; called by muse, mutect2, varscan2
- ITGA8 | c.2832C>T p.S944= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs760075840, COSV65224177, COSV65234732; called by muse, mutect2, varscan2
- PLXNA4 | c.1437C>A p.G479= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV58159233; called by muse, mutect2, varscan2
- PPFIA3 | c.2850C>T p.G950= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs765574283, COSV53256982, COSV53258759; called by muse, mutect2, varscan2
- RB1 | c.2364C>T p.S788= | Silent (SNP) | VAF 42/162 reads (26%) | catalogued as COSV57327048; called by muse, mutect2, varscan2
- RPL14 | c.30C>T p.G10= | Silent (SNP) | VAF 5/95 reads (5%) | catalogued as rs1159042433, COSV59083901; called by muse, mutect2
- SLC45A1 | c.1500C>T p.S500= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs775328773, COSV57092640, COSV57100202; called by muse, mutect2, varscan2
- SNORD116-27 | n.74C>T | RNA (SNP) | VAF 6/38 reads (16%) | catalogued as rs1223536736; called by muse, mutect2, varscan2
